Gene-level copy-number profile of tumor specimen TCGA-N9-A4Q1-01A from TCGA case TCGA-N9-A4Q1, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage II; Age at diagnosis: 70.6 years (25,791 days).
Specimen TCGA-N9-A4Q1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.a4515cff-b20d-482b-a0bd-c45b8266e563.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N9-A4Q1-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/acf787fb-ecfd-4c12-b638-19a803e1499f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,723; copy number 2: 24,009; copy number 3: 11,239; copy number 4: 18,522; copy number 5: 1,708; copy number 6: 597; copy number 7: 319; copy number 8: 616; copy number 9: 37; copy number 12: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N9-A4Q1-01A-11D-A28Q-01): tumor purity 0.88, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,313 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,749,662–156,282,825, 29 genes, copy number 7 (within-gene range 4–7): GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5.
- chr1:238,238,943–240,475,187, 25 genes, copy number 7–8 (within-gene range 4–8): AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1.
- chr2:38,814–2,331,664, 41 genes, copy number 5: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1.
- chr2:4,514,204–5,556,031, 6 genes, copy number 5: NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1, AC107057.1.
- chr2:21,221,169–22,861,884, 14 genes, copy number 5 (within-gene range 4–5): AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830, LINC01884, RN7SKP27.
- chr2:49,202,126–52,961,452, 30 genes, copy number 5 (within-gene range 4–5): AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:76,185,020–84,350,774, 70 genes, copy number 6 (broad region; genes not listed).
- chr3:8,619,400–8,745,040, 2 genes, copy number 5 (within-gene range 2–5): SSUH2, OR7E122P.
- chr3:86,258,936–88,601,402, 26 genes, copy number 5: AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5.
- chr3:93,843,764–97,752,460, 28 genes, copy number 5–6 (within-gene range 4–6): RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:164,001,606–198,222,513, 638 genes, copy number 6–9 (broad region; genes not listed).
- chr4:19,098,199–23,904,089, 35 genes, copy number 5: AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1.
- chr6:17,092,714–63,616,361, 1,254 genes, copy number 5–7 (broad region; genes not listed).
- chr6:65,302,522–67,625,464, 11 genes, copy number 5–9: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA.
- chr6:111,599,875–111,602,295, 1 gene, copy number 7: Z97989.1.
- chr8:40,900,016–42,737,407, 46 genes, copy number 6: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2.
- chr8:87,867,601–90,053,633, 19 genes, copy number 7 (within-gene range 3–7): AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1.
- chr8:91,542,924–92,144,435, 7 genes, copy number 8: AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1.
- chr10:112,283,400–112,446,917, 7 genes, copy number 6: TECTB, MIR6715B, MIR6715A, GUCY2GP, ACSL5, AL157786.1, ZDHHC6.
- chr10:112,548,632–112,548,872, 1 gene, copy number 6: AC022018.1.
- chr11:15,864,452–15,930,951, 2 genes, copy number 6: AC009869.1, LINC02682.
- chr11:15,969,533–15,969,621, 1 gene, copy number 6: MIR6073.
- chr11:76,860,867–77,215,241, 6 genes, copy number 5 (within-gene range 3–5): ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A.
- chr11:118,436,490–118,750,263, 16 genes, copy number 5 (within-gene range 3–5): KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P, PHLDB1, AP000941.1, MIR6716, TREH, TREHP1, AP002954.1, RNU6-376P, AP002954.2.
- chr12:56,162,359–56,382,711, 20 genes, copy number 6 (within-gene range 4–6): SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1.
- chr12:95,516,560–95,858,839, 7 genes, copy number 6 (within-gene range 4–6): USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410.
- chr13:42,255,873–47,459,234, 102 genes, copy number 5 (broad region; genes not listed).
- chr15:86,078,809–87,703,852, 14 genes, copy number 5: LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1, AC012229.1, AC016987.2, AC016987.1, AC078905.1, AC020687.1, RNU6-185P, LINC00052, AC103871.1.
- chr16:7,301,605–15,413,271, 197 genes, copy number 6–8 (broad region; genes not listed).
- chr16:18,781,295–19,553,408, 31 genes, copy number 7: RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, LINC02858, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110.
- chr16:30,407,414–34,142,849, 245 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:75,441,159–75,708,062, 12 genes, copy number 8: TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1.
- chr19:27,638,483–30,228,715, 63 genes, copy number 6–8 (broad region; genes not listed).
- chr19:32,597,006–32,676,597, 1 gene, copy number 7 (within-gene range 2–7): ANKRD27.
- chr19:32,636,078–36,008,813, 169 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr20:31,257,664–32,743,567, 67 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr20:35,615,829–36,270,918, 28 genes, copy number 6: SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2.
- chr21:18,561,265–21,797,415, 32 genes, copy number 5: MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425.
- chr22:42,553,617–42,721,298, 10 genes, copy number 5: SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL, A4GALT.

Autosomal genes at a single copy (total copy number 1): 1,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
